Surgical pathology report (de-identified scan), TCGA case TCGA-23-1114, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1114-01B (Primary Tumor).

[page 1 of 4]
DIAGNOSIS:

1. SMALL BOWEL ADHESION, LYSIS:
- Fibrous adhesion
- Necrotic cellular debris with fragments of high-grade adenocarcinoma
2. OMENTUM, PARTIAL OMENTECTOMY AND FROZEN SECTION #1:
- Adenocarcinoma, high nuclear grade, consistent with mullerian origin
3. OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY:
- Left ovary:
- Papillary adenocarcinoma, high nuclear grade (nuclear grade grade 3), consistent with mullerian-derived adenocarcinoma, papillary serous type
- Left fallopian tube:
- Papillary adenocarcinoma on the serosal aspect of the fallopian tube
- The rest of the wall of the fallopian tube is not involved with the tumor
4. DIAPHRAGM #1, BIOPSY:
- Papillary adenocarcinoma, mullerian-derived, papillary serous type
5. RIGHT SIDEWALL, BIOPSY:
- Papillary adenocarcinoma, mullerian-derived, papillary serous type
6. BLADDER PERITONEUM, BIOPSY:
- Adenocarcinoma, papillary serous type, mullerian-derived
7. OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY:
- Right ovary:
- Papillary adenocarcinoma, mullerian-derived, papillary serous type
- The tumor shows solid and cystic architectural configuration
- Right fallopian tube:
- Adenocarcinoma is present on the serosal aspect of the fallopian tube
- The rest of the wall is not involved with the tumor
8. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:
- Uterine anterior surface (corpus):
- Tumor implants are present on the anterior peritoneal surface of the uterus

[page 2 of 4]
- Endometrium:
- Mildly disordered inactive endometrium
- Negative for malignancy
- Myometrium:
- Adenomyosis
- Right mesosalpinx/right parametrial soft tissue with adenocarcinoma, papillary serous type, mullerian-derived
9. LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION:
- Five (5) lymph nodes with reactive follicular hyperplasia and sinus histiocytosis
- Negative for malignancy
10. APPENDIX, APPENDECTOMY:
- Metastatic adenocarcinoma is present on the serosal and subserosal aspect of the appendix
- The remainder of the wall of the appendix is negative for malignancy
11. DIAPHRAGM TUMOR #2, BIOPSY:
- Adenocarcinoma, papillary serous type, mullerian-derived

=====

HISTORY: Ovarian carcinoma

MICROSCOPIC:
See Diagnosis.

GROSS:

1: SMALL BOWEL ADHESION

Labeled "small bowel adhesion" and received in formalin is an 8.4 x 0.4 x 0.3 cm serpiginous, tan-brown, membranous portion of tissue.

A. All embedded - 1

2: OMENTUM FROZEN SECTION NO. 1

Labeled "omentum, FS#1", received fresh in the Operating Room, a portion utilized for frozen section diagnosis and subsequently fixed in formalin, is an 11.4 x 9.3 x 4.3 cm portion of focally indurated and dull, tan-red omentum which on sectioning has a diffusely indurated tan-yellow cut surface, consistent with tumor. Representative sections.

B. Frozen section #1 remnant - 2

C. 1

3: LEFT TUBE AND OVARY

Labeled "left tube and ovary" and received in formalin is a 7.7 x 4.8 x 4.4 cm markedly enlarged ovary. The external surface is tan-pink and almost entirely surfaced with abundant friable excrescences. On sectioning, cut surfaces range from solid to focally cystic with cystic locules ranging from 0.6 up to 2.4 cm in greatest dimension. There is no recognizable ovarian parenchyma. There is an attached 4.4 x 0.6 x 0.5 cm segment of fimbriated fallopian tube which is surrounded by the friable tumor mass. On section, cut surfaces are edematous. There is a 0.2 cm patent lumen. Representative sections.

D-G. Ovarian mass - 1 each

H. Fallopian tube - 2

4: DIAPHRAGM TUMOR NO. 1

Labeled "diaphragm tumor #1" and received in formalin, are three irregular, soft, tan-grey tissue fragments ranging from 0.5 to 1.7 cm in greatest dimension.

[page 3 of 4]
I. All embedded - 3

5: RIGHT SIDE WALL TUMOR

Labeled "right sidewall tumor" and received in formalin is an irregular fragment of tissue, measuring 1.3 x 0.7 x 0.5 cm in greatest dimension.

J. Representative section - 1

6: BLADDER PERITONEUM

Labeled "bladder peritoneum" and received in formalin is a 1.7 x 1.3 x 1.2 cm irregular, soft, friable, tan-brown, hemorrhagic tissue fragment which is bisected.

K. All embedded - 2

7: RIGHT TUBE AND OVARY

Labeled "right tube and ovary" and received in formalin is a 4.8 x 4.6 x 3.2 cm enlarged, firm ovary. The external surface is almost entirely covered by friable, tan-red, granular and hemorrhagic excrescences. On sectioning, the cut surfaces vary from solid to cystic with a 1.7 cm cystic locule containing abundant blood clot. There is a 2.5 cm foci of friable tissue. No residual ovarian parenchyma is identified. Adherent to the external surface of the ovary is a 4.4 x 0.6 x 0.5 cm fimbriated length of fallopian tube. On sectioning, cut surfaces are markedly edematous with a 0.1 cm patent lumen. Representative sections.

L,M. Solid portion of mass - 1 each

N,O. Cystic portion of mass - 1 each

P. Fallopian tube - 2

8: UTERUS

Labeled "uterus", received fresh in the Operating Room for intraoperative consultation and subsequently fixed in formalin, is a 75 gram supracervical hysterectomy without attached adnexa. The serosa is shaggy and focally torn, tan-red, with abundant foci of hemorrhage. There is abundant attached right mesosalpinx. The uterine body is 3.9 cm superior to inferior, 4.2 cm cornu to cornu and 2.4 cm anterior to posterior. The myometrium measures up to 1.4 cm and is firm, tan-pink and trabeculated without intramural lesions. The endometrial canal is 2.7 cm in length and 1.7 cm in width. The endometrium is smooth and tan-pink, measuring up to 0.2 cm in thickness. No endometrial lesions are identified. Representative sections.

Q. Anterior uterine corpus - 1

R. Posterior uterine corpus - 1

S. Right mesosalpinx - 2

9: LEFT EXTERNAL ILIAC LYMPH NODE

Labeled "left external iliac lymph node" and received in formalin is a 3.2 x 1.4 x 0.4 cm firm, tan-red lymph node which on sectioning has a homogeneous, tan-pink cut surface. No obvious tumor is identified.

T,U. All embedded - 1 each

10: APPENDIX

Labeled "appendix" and received in formalin, is a 4.7 x 0.6 x 0.6 cm vermiform appendix with a moderate amount of adherent, focally indurated adipose tissue. The serosa is tan-white and smooth with focal adherent granularity and hemorrhage. No obvious area of perforation is identified. On sectioning, the lumen contains minimal hemorrhagic material. The wall thickness averages 0.2 cm throughout and the lumen averages 0.1 cm throughout. No fecolith is identified.

V. Representative sections - 3

[page 4 of 4]
11: DIAPHRAGM TUMOR NO. 2

Labeled "diaphragm tumor #2" and received in formalin is a 2.6 x 2.3 x 1.3 cm aggregate of soft, tan-white, granular tissue and blood clot.

W. Representative sections - Multiple

[REDACTED]

OPERATIVE CONSULT (GROSS):

#8: Uterus (supracervical hysterectomy) and endometrium without significant gross pathology

[REDACTED]

OPERATIVE CONSULT (FROZEN):

FS#1: Adenocarcinoma consistent with mullerian origin

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 32857435-06f2-4055-aec5-e782be8cf2e3 (TCGA-23-1114.D5C00586-D7E4-4909-BE2B-FFC4F9EF2E82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).